Surgical pathology report (de-identified scan), TCGA case TCGA-E1-5307, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-5307-01A (Primary Tumor).

[page 1 of 2]
Clinical History:

Not provided.

Gross Examination:

A. "Brain tumor (AF1-2)", received fresh for frozen section. A 7 x 6.5 x 3 cm roughly ovoid fragment of brain has been previously sectioned exhibiting that the architecture is obscured by a fleshy yellow-tan tissue on cut surface. Representative has been previously submitted as frozen sections AF1-2. The frozen section remnants are submitted respectively in A1-2. Representative of the non frozen tissue is submitted in A3-8.

B. "Brain tumor", received fresh and placed in formalin. A 3.8 x 2.6 x 1.2 cm aggregate of two irregular fragments of soft pink tissue is received. Representative of each fragment submitted in B1-2.

Intraoperative Consultation:

A. "Brain tumor": AF1- glioma, grade deferred

Microscopic Examination:

Sections of the brain tumor shows a malignant glial neoplasm. In some areas there is a suggestion of oligodendroglial differentiation with microcysts and a suggestion of a perineuronal satellitosis. Delicate arcuating vessels typical of oligodendroglioma are not observed. There are foci of small malignant gemistocytic cells. Frank necrosis is not observed.

DIAGNOSIS:

A. "BRAIN TUMOR":

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

B. "BRAIN TUMOR":

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

Continued on next page...

Page: 1
DATE:

Patient:
MRN:
Location:

[page 2 of 2]
DIAGNOSIS:

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed:

** END OF REPORT **

Page: 2
DATE:

Patient
HX No
Location

Source: NCI Genomic Data Commons file 3aa95123-b37f-4d36-9db6-e955838d5ee0 (TCGA-E1-5307.60B202DB-3C7C-4C86-BE48-9EF37C9039A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).